Somatic mutation profile of tumor specimen MMRF_2007_1_BM_CD138pos (aliquot MMRF_2007_1_BM_CD138pos_T1_KBS5U_L07283) from MMRF case MMRF_2007, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,410 days).
Specimen MMRF_2007_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 419fdb97-6e94-435a-95b2-e552f9ddd3db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2007_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2007_1_PB_Whole_C2_KBS5U_L07284; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce97802a-b5db-4a89-9275-ab92b92056b0

The open-access MAF lists 98 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 31, Missense Mutation 30, Silent 13, Intron 11, 5'Flank 5, 5'UTR 3, RNA 2, 3'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 67/125 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- FIGN | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV60763213; called by muse, mutect2, varscan2
- FOXO3 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs767626656; called by mutect2, varscan2
- IGHV2-70 | c.190A>T p.K64* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs747883300; called by muse, varscan2
- IGHV2-70 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs530408879; called by muse, varscan2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, mutect2, varscan2
- IGKV2D-29 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs373343547; called by muse, mutect2, varscan2
- IGLV3-1 | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs61736464; called by muse, varscan2
- IGLV3-1 | c.148T>G p.Y50D | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs368495152; called by muse, varscan2
- IGLV3-1 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs61731690; called by muse, varscan2
- NSD1 | c.3134G>A p.R1045H | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1359539320, CM142516; called by muse, mutect2, varscan2
- OR4M1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV60059808; called by muse, mutect2, varscan2
- SEMA3B | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as rs1553706538; called by muse, mutect2, varscan2
- AJM1 | c.1000T>A p.F334I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ANTXR2 | c.1454T>C p.V485A | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCT4 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CHPT1 | c.189dup p.N64Qfs*51 | Frame Shift Ins (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- CMTM2 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- DNAI3 | c.2332A>G p.I778V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM149A | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- FUCA1 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- HK1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- IGLV3-1 | c.189_191delinsATC p.L64S | Missense Mutation (TNP) | VAF 19/37 reads (51%) | called by muse*, pindel, varscan2*
- MYO3B | c.1891G>T p.V631L | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NOP2 | c.1228G>T p.G410C (on ENST00000322166 / NM_001258308.2; = p.G406C on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R18 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF180 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 122/254 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A6 | c.136A>C p.S46R | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SOX6 | c.1357A>C p.T453P (on ENST00000528429 / NM_001145819.2; = p.T412P on NM_017508.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STARD9 | c.13520T>C p.L4507S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STT3A | c.1788T>G p.F596L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AGAP2 | c.1620A>G p.K540= (on ENST00000547588 / NM_001122772.2; = p.K204= on NM_014770.4) | Silent (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5952A>T p.P1984= | Silent (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- AUTS2 | c.978G>A p.Q326= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- CD163L1 | c.84C>T p.C28= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- COL11A1 | c.1527C>T p.I509= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- FAM178B | c.672G>A p.E224= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- HMCN1 | c.7884C>T p.G2628= | Silent (SNP) | VAF 62/113 reads (55%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.87G>A p.A29= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as rs369078954; called by muse, varscan2
- NLRP12 | c.1590G>A p.E530= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs751967123; called by muse, mutect2, varscan2
- PDE6B | c.336C>T p.S112= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs1196365702, COSV99073038; called by muse, mutect2, varscan2
- PPFIA4 | c.108G>A p.E36= | Silent (SNP) | VAF 43/122 reads (35%) | called by muse, mutect2, varscan2
- TNFSF13B | c.588T>C p.Y196= | Silent (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.1774C>T p.L592= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- ACTB | c.985-28C>T | Intron (SNP) | VAF 37/67 reads (55%) | catalogued as rs1386436120; called by muse, mutect2, varscan2
- ADCY2 | c.*2660T>A | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.*2630A>G | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031090 C>A | 5'Flank (SNP) | VAF 55/96 reads (57%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021568 A>G | 5'Flank (SNP) | VAF 20/45 reads (44%) | catalogued as COSV55849570; called by muse, mutect2, varscan2
- CADM1 | chr11:115504504 A>G | 5'Flank (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- CCNDBP1 | c.*1012T>A | 3'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- CEP170B | c.*458G>C | 3'UTR (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- CFLAR | c.524-1384del | Intron (DEL) | VAF 93/248 reads (38%) | called by mutect2, pindel, varscan2
- CLOCK | c.*619A>C | 3'UTR (SNP) | VAF 30/71 reads (42%) | catalogued as rs532831636; called by muse, mutect2, varscan2
- COL11A1 | c.*268T>A | 3'UTR (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- CPEB3 | c.-119C>T | 5'UTR (SNP) | VAF 10/16 reads (63%) | catalogued as rs530679746; called by muse, varscan2
- CRISPLD2 | c.1305+86C>T | Intron (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- CX3CR1 | c.*9C>G | 3'UTR (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- DCHS2 | n.735T>G | RNA (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- EPHA7 | c.*1177T>A | 3'UTR (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- ERBB4 | c.*2718A>C | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- FAM229B | c.*1242C>A | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- FBXL7 | c.*1585G>T | 3'UTR (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- GFUS | c.811-31C>T | Intron (SNP) | VAF 51/124 reads (41%) | catalogued as rs769023269; called by muse, mutect2, varscan2
- GYPA | c.*310G>T | 3'UTR (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- HACD4 | c.-25C>T | 5'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- HIBCH | c.-70G>T | 5'UTR (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863448 G>C | 5'Flank (SNP) | VAF 6/13 reads (46%) | catalogued as rs1566848152; called by muse, varscan2
- KCMF1 | c.*2082T>G | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- KRT33B | c.*47C>A | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- LGR6 | chr1:202188947 G>A | 5'Flank (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- MAPK14 | c.*676T>G | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- MS4A6A | c.282+216C>G | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- MST1L | n.2132G>A | RNA (SNP) | VAF 25/419 reads (6%) | called by muse, mutect2
- NCMAP | c.*271A>G | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- NLRC5 | c.4154+59G>A | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- NRBP2 | c.129+144C>T | Intron (SNP) | VAF 5/9 reads (56%) | catalogued as rs959457584; called by muse, mutect2, varscan2
- NUDT16 | c.408+131G>A | Intron (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- PCP4 | c.*271C>T | 3'UTR (SNP) | VAF 30/76 reads (39%) | catalogued as rs888026555; called by muse, mutect2, varscan2
- PKN2 | c.*309dup | 3'UTR (INS) | VAF 39/89 reads (44%) | called by mutect2, varscan2
- RAB3C | c.*6957C>T | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- RBBP5 | c.*900A>G | 3'UTR (SNP) | VAF 52/75 reads (69%) | called by muse, mutect2, varscan2
- RICTOR | c.*1243A>C | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.*1753A>T | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- RTBDN | c.462+353C>T | Intron (SNP) | VAF 15/32 reads (47%) | catalogued as rs529112099; called by muse, mutect2, varscan2
- RTL8C | c.*506G>A | 3'UTR (SNP) | VAF 100/102 reads (98%) | called by muse, mutect2, varscan2
- SPRED1 | c.*1827C>A | 3'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- SPSB2 | c.665-337G>C | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- SYBU | c.*349T>C | 3'UTR (SNP) | VAF 77/153 reads (50%) | called by muse, mutect2, varscan2
- TMEM135 | c.*904A>G | 3'UTR (SNP) | VAF 39/79 reads (49%) | catalogued as rs765675071; called by muse, mutect2, varscan2
- TRARG1 | c.*1599C>T | 3'UTR (SNP) | VAF 32/86 reads (37%) | catalogued as rs780064578; called by muse, mutect2, varscan2
- ULK2 | c.*40+1351A>G | Intron (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- USP34 | chr2:61183597 T>C | 3'Flank (SNP) | VAF 25/54 reads (46%) | catalogued as rs747056891; called by muse, mutect2, varscan2
- VCPIP1 | c.*923A>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | catalogued as rs956207347, COSV60047586; called by muse, mutect2
- ZMYM4 | c.*2083T>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- ZNF681 | c.*3045C>T | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.*280del | 3'UTR (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
